Somatic mutation profile of tumor specimen C3L-00097-01 (aliquot CPT0000780005) from CPTAC case C3L-00097, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.2 years (21,624 days).
Specimen C3L-00097-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1265ece-37c4-4be5-b511-9ae0d678a178.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00097-31 (Blood Derived Normal), aliquot CPT0003920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/653fa983-3881-41ce-9d08-e4e2066b7bf9

The open-access MAF lists 95 somatic variants for this specimen: 72 protein-altering or splice-affecting, 12 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 12, Intron 8, Frame Shift Del 7, Nonsense Mutation 4, Frame Shift Ins 4, In Frame Del 3, Splice Site 2, 5'UTR 1, Splice Region 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 48/204 reads (24%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- VHL | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 77/205 reads (38%) | catalogued as rs5030802, CM951268, CM984688, COSV56544079; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COX15 | c.686C>A p.S229* | Nonsense Mutation (SNP) | VAF 113/379 reads (30%) | catalogued as rs201002908; called by muse, mutect2, varscan2
- FGFR2 | c.1387G>T p.V463F | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV60656427; called by muse, mutect2
- GNGT1 | c.129C>A p.Y43* | Nonsense Mutation (SNP) | VAF 18/148 reads (12%) | catalogued as COSV50352382; called by muse, mutect2, varscan2
- GOLGA6L10 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 116/1088 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.503); catalogued as rs1234347769; called by muse, mutect2, varscan2
- GTF2H3 | c.858G>A p.E286= | Splice Region (SNP) | VAF 27/88 reads (31%) | catalogued as COSV99967575; called by muse, varscan2
- LIFR | c.828del p.V277Cfs*5 | Frame Shift Del (DEL) | VAF 62/228 reads (27%) | catalogued as COSV99663575; called by mutect2, pindel, varscan2
- LRRC8A | c.1621C>T p.R541W | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV52187695; called by muse, mutect2, varscan2
- MEF2A | c.1354C>T p.P452S (on ENST00000557942 / NM_001319206.2; = p.P446S on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/248 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1477329333; called by muse, mutect2
- NUGGC | c.2348G>C p.R783T | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); catalogued as COSV58434605; called by muse, varscan2
- RYR1 | c.13837G>C p.G4613R | Missense Mutation (SNP) | VAF 77/233 reads (33%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.967); catalogued as COSV62097335; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2577G>C p.M859I | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV51955289; called by muse, mutect2
- ZNF197 | c.466C>T p.L156F | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0.053); catalogued as COSV60360641; called by muse, mutect2, varscan2
- ACADS | c.14T>A p.L5Q | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ACAP1 | c.1576A>C p.I526L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADAMTS5 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 86/186 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- ANKRD36C | c.4624G>A p.A1542T | Missense Mutation (SNP) | VAF 106/434 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.494); called by muse, varscan2
- ARHGAP24 | c.2197A>T p.T733S (on ENST00000395184 / NM_001025616.3; = p.T640S on NM_031305.3) | Missense Mutation (SNP) | VAF 101/319 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ARHGEF25 | c.682_690del p.C228_K230del | In Frame Del (DEL) | VAF 34/174 reads (20%) | called by mutect2, pindel, varscan2
- BACH1 | c.2160del p.I721Sfs*8 | Frame Shift Del (DEL) | VAF 42/95 reads (44%) | called by mutect2, pindel, varscan2
- C1orf127 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CATSPER1 | c.2222A>T p.H741L | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CFAP65 | c.572T>A p.V191D | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- CHRNA4 | c.785T>C p.V262A | Missense Mutation (SNP) | VAF 107/421 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- DCHS1 | c.8918G>T p.G2973V | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- DDX53 | c.274A>G p.K92E | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DGCR8 | c.1067A>G p.K356R | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPT | c.421T>C p.Y141H | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EIF2AK2 | c.1582_1590del p.N528_S530del | In Frame Del (DEL) | VAF 28/214 reads (13%) | called by mutect2, pindel, varscan2
- ETNK1 | c.780T>A p.F260L | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- FBLN2 | c.2890C>A p.Q964K | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GIPC1 | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- GRAMD1A | c.729_730dup p.E244Gfs*6 | Frame Shift Ins (INS) | VAF 11/69 reads (16%) | called by mutect2, pindel, varscan2
- HTR5A | c.336G>T p.R112S | Missense Mutation (SNP) | VAF 104/240 reads (43%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCTD18 | c.696dup p.E233Rfs*30 | Frame Shift Ins (INS) | VAF 50/209 reads (24%) | called by mutect2, pindel, varscan2
- KIAA1217 | c.1426C>G p.H476D | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KRTAP19-3 | c.148T>A p.F50I | Missense Mutation (SNP) | VAF 93/546 reads (17%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MIA3 | c.5022_5024del p.G1675del | In Frame Del (DEL) | VAF 18/86 reads (21%) | called by pindel, varscan2
- MYOCD | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.772); called by muse, varscan2
- NCKAP5 | c.4502A>G p.K1501R | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- NCKAP5 | c.4501A>T p.K1501* | Nonsense Mutation (SNP) | VAF 55/200 reads (28%) | called by muse, mutect2, varscan2
- NOP56 | c.1051A>C p.I351L | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- OR1S1 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 58/277 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- PET117 | c.23T>C p.V8A | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.2); called by muse, mutect2, varscan2
- PEX16 | c.230T>A p.L77Q | Missense Mutation (SNP) | VAF 61/251 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- PKD2L2 | c.704T>A p.F235Y | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLM | c.1229C>A p.P410Q | Missense Mutation (SNP) | VAF 46/277 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POM121 | c.721T>A p.C241S | Missense Mutation (SNP) | VAF 56/394 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRICKLE1 | c.1041del p.R347Sfs*10 | Frame Shift Del (DEL) | VAF 23/62 reads (37%) | called by mutect2, pindel, varscan2
- PTGR2 | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- R3HDM1 | c.172-1G>A p.X58_splice | Splice Site (SNP) | VAF 29/137 reads (21%) | called by muse, mutect2, varscan2
- RAPGEFL1 | c.903C>G p.D301E | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- RERE | c.3563A>G p.K1188R | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- RIMS1 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SHMT1 | c.697dup p.S233Kfs*14 | Frame Shift Ins (INS) | VAF 139/553 reads (25%) | called by mutect2, pindel, varscan2
- SMAD3 | c.431C>T p.T144I | Missense Mutation (SNP) | VAF 78/237 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- SMC4 | c.2675T>A p.V892E | Missense Mutation (SNP) | VAF 65/249 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- STK10 | c.2759G>C p.R920P | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYN3 | c.323T>G p.F108C | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYNE1 | c.16388del p.K5463Rfs*7 (on ENST00000367255 / NM_182961.4; = p.K5392Rfs*7 on NM_033071.3) | Frame Shift Del (DEL) | VAF 71/296 reads (24%) | called by mutect2, pindel, varscan2
- TCTN1 | c.657del p.L220* | Frame Shift Del (DEL) | VAF 136/522 reads (26%) | called by pindel, varscan2
- TPX2 | c.1885C>T p.P629S | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- TSPYL1 | c.97del p.Y33Tfs*2 | Frame Shift Del (DEL) | VAF 56/202 reads (28%) | called by mutect2, pindel*, varscan2
- UBA2 | c.1482A>T p.E494D | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- UGT2B10 | c.169T>C p.S57P | Missense Mutation (SNP) | VAF 12/307 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0.014); called by muse, mutect2
- ZBTB16 | c.1759C>A p.H587N | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ZFC3H1 | c.3574G>A p.G1192R | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF222 | c.556T>A p.S186T | Missense Mutation (SNP) | VAF 106/356 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ZNF25 | c.277del p.Q93Rfs*42 | Frame Shift Del (DEL) | VAF 49/233 reads (21%) | called by mutect2, pindel, varscan2
- ZNF346 | c.373-33_375del p.X125_splice | Splice Site (DEL) | VAF 32/132 reads (24%) | called by mutect2, pindel
- ZSCAN23 | c.772T>G p.F258V | Missense Mutation (SNP) | VAF 77/272 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH7 | c.975A>T p.I325= | Silent (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- HIVEP3 | c.4005C>T p.Y1335= | Silent (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- IQCN | c.1857A>C p.A619= | Silent (SNP) | VAF 57/195 reads (29%) | called by muse, mutect2, varscan2
- NHS | c.549T>C p.P183= | Silent (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- NPSR1 | c.297G>C p.L99= | Silent (SNP) | VAF 52/106 reads (49%) | called by muse, mutect2
- SGMS2 | c.831G>C p.V277= | Silent (SNP) | VAF 28/142 reads (20%) | called by muse, mutect2, varscan2
- TNKS1BP1 | c.3504G>A p.R1168= | Silent (SNP) | VAF 46/186 reads (25%) | catalogued as COSV100836321; called by muse, mutect2, varscan2
- TRAF2 | c.444G>A p.K148= | Silent (SNP) | VAF 41/149 reads (28%) | catalogued as rs750814825; called by muse, mutect2, varscan2
- TXNL4A | c.348C>A p.I116= | Silent (SNP) | VAF 42/135 reads (31%) | catalogued as rs1445169904, COSV54099118; called by muse, mutect2, varscan2
- WWC3 | c.213C>T p.Y71= | Silent (SNP) | VAF 41/65 reads (63%) | catalogued as rs751017696; called by muse, mutect2, varscan2
- ZNF512 | c.1038T>C p.A346= | Silent (SNP) | VAF 28/136 reads (21%) | called by muse, mutect2, varscan2
- ZNF850 | c.1380G>A p.S460= | Silent (SNP) | VAF 39/193 reads (20%) | catalogued as rs756632168; called by muse, mutect2, varscan2
- DGKZ | c.1009-19T>C | Intron (SNP) | VAF 37/126 reads (29%) | called by muse, mutect2, varscan2
- HEXB | c.446-17T>G | Intron (SNP) | VAF 83/318 reads (26%) | catalogued as rs1183671097; called by muse, mutect2, varscan2
- IGFN1 | c.1241+2452_1241+2466del | Intron (DEL) | VAF 16/47 reads (34%) | called by mutect2, pindel, varscan2
- MLXIPL | c.1823-47T>A | Intron (SNP) | VAF 110/236 reads (47%) | called by muse, mutect2, varscan2
- OXA1L | c.244-214G>A | Intron (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- OXA1L | c.244-213A>G | Intron (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2, varscan2
- PGM5 | c.-1C>T | 5'UTR (SNP) | VAF 22/58 reads (38%) | called by muse, varscan2
- POLR3H | c.208+129_208+130dup | Intron (INS) | VAF 69/307 reads (22%) | called by mutect2, pindel, varscan2
- RNA5-8SP2 | chr16:34159464 del G | 5'Flank (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- SENP1 | c.221-299G>T | Intron (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- ZNF849P | n.631A>C | RNA (SNP) | VAF 84/239 reads (35%) | called by muse, mutect2, varscan2
